CCDI case PBCIAS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/f3383e45-6747-4add-b325-b28ac980ba2e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Nodular melanoma: ICD-O-3 morphology code: 8721/3; Tissue or organ of origin: Skin of trunk; Age at diagnosis: 10.9 years (3,985 days).

Biospecimens (3 samples)
- Sample 0DT3U6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT3UF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DT3UO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
